Somatic mutation profile of tumor specimen TCGA-L7-A6VZ-01A (aliquot TCGA-L7-A6VZ-01A-12D-A33E-09) from TCGA case TCGA-L7-A6VZ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 62.2 years (22,730 days).
Specimen TCGA-L7-A6VZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef4f14df-ac5a-4e9c-a228-05ea0ab12914.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L7-A6VZ-10A (Blood Derived Normal), aliquot TCGA-L7-A6VZ-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c53a45e5-533a-4a64-81ee-de70a1928f07

The open-access MAF lists 140 somatic variants for this specimen: 98 protein-altering or splice-affecting, 40 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 40, Nonsense Mutation 3, In Frame Del 2, Splice Region 2, Frame Shift Ins 2, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MC2R | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs139218324, CM116421; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 11/21 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1511132, COSV52737174, COSV52760297, COSV52868891; called by muse, mutect2, varscan2
- ADCY5 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250075271; called by muse, mutect2, varscan2
- ADCY8 | c.523T>G p.L175V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.074); catalogued as COSV53900685; called by muse, mutect2, varscan2
- ANGPTL8 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1487060387; called by muse, mutect2, varscan2
- ANKRD30A | c.3051A>C p.K1017N (on ENST00000611781; = p.K961N on NM_052997.2) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV64603900, COSV64607723, COSV64608830; called by muse, mutect2, varscan2
- ARF1 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99682987, COSV99683009; called by muse, mutect2, varscan2
- CDKN2A | c.150+1G>T p.X50_splice | Splice Site (SNP) | VAF 14/20 reads (70%) | catalogued as COSV58682660, COSV58691878; called by muse, mutect2, varscan2
- CHRNA7 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs573369306, COSV60970070; called by muse, mutect2, varscan2
- CTNNA2 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs756019081, COSV63558850; called by muse, mutect2, varscan2
- DDO | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64470725; called by muse, mutect2, varscan2
- DNAH17 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.651); catalogued as rs777329899, COSV67752513; called by muse, mutect2, varscan2
- DNAH5 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.041); catalogued as rs140388814; called by muse, mutect2, varscan2
- DOCK2 | c.2438A>C p.K813T | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.398); catalogued as COSV56941136; called by muse, mutect2, varscan2
- EAF2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs757455230; called by muse, mutect2, varscan2
- FARP1 | c.2435T>C p.I812T | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs781266897; called by muse, mutect2, varscan2
- GABRA6 | c.79T>G p.F27V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV50880334, COSV50881677, COSV50882038; called by muse, mutect2, varscan2
- GABRA6 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1270279109, COSV50877438, COSV99194040; called by muse, mutect2, varscan2
- GALNT17 | c.43T>G p.L15V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); catalogued as COSV61195349; called by muse, mutect2, varscan2
- GRIA1 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1194364279, COSV53597870; called by muse, mutect2, varscan2
- GRM4 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 55/62 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs781055557; called by muse, mutect2, varscan2
- HDLBP | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV60499000; called by muse, mutect2, varscan2
- HMCN1 | c.7327C>T p.R2443W | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376132541; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV3-11 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.725); catalogued as rs782705452; called by muse, mutect2, varscan2
- IRF4 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706083; called by muse, mutect2, varscan2
- IVL | c.445A>G p.K149E | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs200731333; called by muse, mutect2, varscan2
- L1CAM | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT tolerated (0.19); PolyPhen benign (0.284); catalogued as rs1557092050, COSV62829666; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN5 | c.59G>T p.C20F | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53278124; called by muse, mutect2, varscan2
- LRRTM4 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427573465, COSV69142013; called by muse, mutect2, varscan2
- MACROD2 | c.1216G>C p.E406Q (on ENST00000642719; = p.E378Q on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV53948495; called by muse, mutect2, varscan2
- MEGF10 | c.1769G>T p.G590V | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99175044; called by muse, mutect2, varscan2
- MUC5B | c.5921C>A p.T1974K | Missense Mutation (SNP) | VAF 103/130 reads (79%) | SIFT tolerated (0.23); PolyPhen benign (0.135); catalogued as COSV101499981; called by muse, mutect2, varscan2
- NALCN | c.1059A>C p.E353D | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.53); PolyPhen benign (0.04); catalogued as rs777751467, COSV51915430, COSV51931323; called by muse, mutect2, varscan2
- NAV2 | c.7187A>G p.D2396G (on ENST00000396087 / NM_001244963.2; = p.D2337G on NM_145117.5) | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.505); catalogued as rs369324745; called by muse, mutect2, varscan2
- NAV3 | c.5692G>C p.D1898H (on ENST00000397909 / NM_001024383.2; = p.D1876H on NM_014903.6) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs765707660, COSV99894044; called by muse, mutect2, varscan2
- OLFM1 | c.364G>A p.V122M (on ENST00000371793 / NM_001282611.2; = p.V104M on NM_006334.4) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs1205344491, COSV52963450; called by muse, mutect2
- OMA1 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | catalogued as rs576005631; called by muse, mutect2, varscan2
- OR5L2 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV65724970; called by muse, mutect2, varscan2
- PCNX2 | c.5609G>A p.R1870Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.64); catalogued as rs766878027, COSV99267156; called by muse, mutect2, varscan2
- PRAMEF15 | c.464T>G p.L155R | Missense Mutation (SNP) | VAF 64/440 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1270312537; called by muse, mutect2
- PTPRT | c.2314A>C p.R772= | Splice Region (SNP) | VAF 22/85 reads (26%) | catalogued as COSV61982822; called by muse, mutect2, varscan2
- RAB40AL | c.185G>C p.R62P | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54433906; called by muse, mutect2, varscan2
- ST6GAL2 | c.81C>A p.F27L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | PolyPhen benign (0.089); catalogued as COSV64526753; called by muse, mutect2, varscan2
- STX1A | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs782328797, COSV56095702; called by muse, mutect2, varscan2
- STX1B | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs368619665; called by muse, mutect2, varscan2
- TENM4 | c.6712C>T p.R2238W | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779398356, COSV53648374; called by muse, mutect2, varscan2
- TRIM49 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV61670316; called by muse, mutect2, varscan2
- TRIM55 | c.467G>T p.C156F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1171533284; called by muse, mutect2, varscan2
- TRPM6 | c.4560G>T p.Q1520H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs768065375; called by muse, mutect2, varscan2
- TTN | c.36244G>A p.G12082S (on ENST00000591111; = p.G4658S on NM_003319.4) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | PolyPhen probably damaging (0.999); catalogued as rs188301588; called by muse, mutect2, varscan2
- USP29 | c.1586T>G p.V529G | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99518045; called by muse, mutect2, varscan2
- ZNF274 | c.503G>A p.R168H (on ENST00000610905; = p.R63H on NM_016324.3) | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs767709584, COSV58762826; called by muse, mutect2, varscan2
- ZNF43 | c.2174A>C p.K725T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV61686480; called by muse, mutect2, varscan2
- ZNF555 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs201040185; called by muse, mutect2, varscan2
- ZNF831 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV64039574; called by muse, mutect2, varscan2
- ZNRF4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149951234, COSV55773111, COSV55774967; called by muse, mutect2, varscan2
- ATP5PB | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C21orf91 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CCDC112 | c.1288dup p.I430Nfs*4 | Frame Shift Ins (INS) | VAF 7/38 reads (18%) | called by mutect2, pindel, varscan2
- CDC42BPA | c.48C>A p.D16E | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL3A1 | c.3800T>A p.F1267Y | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- CSMD1 | c.8071C>T p.H2691Y (on ENST00000520002; = p.H2690Y on NM_033225.6) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); called by muse, mutect2
- DAAM2 | c.2376C>G p.S792R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- DNAH5 | c.7565C>T p.A2522V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- EPAS1 | c.135C>A p.H45Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- EXD3 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM193B | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HBE1 | c.184A>C p.K62Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- HEATR5B | c.4925T>A p.L1642Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHV1-46 | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- IGHV3-35 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- LONP2 | c.1937A>T p.E646V | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP2BP | c.522G>T p.K174N | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRPPRC | c.2390C>T p.A797V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAST4 | c.2252_2281del p.A751_Y760del (on ENST00000403625 / NM_001164664.2; = p.A562_Y571del on NM_015183.3) | In Frame Del (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- MLLT1 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MUC16 | c.11989A>C p.T3997P | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- POF1B | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 59/74 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POLQ | c.1505C>G p.S502* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- PPL | c.5141A>T p.K1714M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRAMEF17 | c.1038A>C p.K346N | Missense Mutation (SNP) | VAF 81/165 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- PRAMEF20 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PTK2 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RRP12 | c.3514A>C p.K1172Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLC4A3 | c.3465G>A p.M1155I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); called by muse, mutect2
- SP140L | c.580A>G p.M194V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPZ1 | c.983G>T p.C328F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SSU72 | c.205_207del p.L69del | In Frame Del (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- TNNC1 | c.335T>C p.I112T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPTE | c.532_533insG p.F178Cfs*3 (on ENST00000618007 / NM_199261.4; = p.F160Cfs*3 on NM_199259.4) | Frame Shift Ins (INS) | VAF 36/130 reads (28%) | called by mutect2, pindel, varscan2
- TTN | c.74905G>T p.A24969S (on ENST00000591111; = p.A17545S on NM_003319.4) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TTN | c.43733T>G p.L14578R (on ENST00000591111; = p.L7154R on NM_003319.4) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UHRF1BP1L | c.4154G>A p.G1385E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP15 | c.1714A>T p.R572* (on ENST00000280377 / NM_001351159.2; = p.R543* on NM_006313.3 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- WDPCP | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.257); called by muse, varscan2
- ZC3H12B | c.781A>G p.K261E | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF174 | c.755C>A p.A252E | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZXDC | c.2127+3A>G | Splice Region (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- ABCA8 | c.4273A>C p.R1425= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- AC134980.2 | c.648T>G p.A216= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV60907289; called by muse, mutect2, varscan2
- ADAM29 | c.975T>G p.T325= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV63663088, COSV63663558; called by muse, mutect2, varscan2
- CBWD5 | c.1173T>C p.D391= (on ENST00000382405 / NM_001330668.1; = p.D343= on NM_001024916.3) | Silent (SNP) | VAF 126/1316 reads (10%) | called by muse, mutect2
- CCDC88A | c.465G>A p.A155= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs374500852, COSV55062797; called by muse, mutect2, varscan2
- CNTN3 | c.726T>G p.G242= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV55161904, COSV99725440; called by muse, mutect2, varscan2
- CPXM1 | c.1347C>T p.D449= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs140373758; called by muse, mutect2, varscan2
- DNAAF3 | c.372G>A p.P124= (on ENST00000524407 / NM_001256715.2; = p.P171= on NM_178837.4) | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1048936417; ClinVar: likely benign; called by muse, varscan2
- DNAH11 | c.13059C>T p.D4353= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV60964066; called by mutect2, varscan2
- EPG5 | c.5937C>T p.N1979= | Silent (SNP) | VAF 41/63 reads (65%) | catalogued as rs150214973; called by muse, mutect2, varscan2
- EPHA5 | c.798T>C p.S266= | Silent (SNP) | VAF 18/30 reads (60%) | called by muse, mutect2, varscan2
- FERD3L | c.246C>T p.R82= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs999975859, COSV51761945; called by muse, mutect2, varscan2
- FGF16 | c.465G>A p.S155= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs781995014, COSV71546240; called by muse, mutect2, varscan2
- GNA13 | c.276G>A p.V92= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs747246606; called by muse, mutect2, varscan2
- GOLGA4 | c.6459G>A p.G2153= | Silent (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- HS3ST4 | c.144G>A p.L48= | Silent (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2
- JHY | c.1776G>A p.T592= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as rs776711079, COSV99913807; called by muse, mutect2, varscan2
- KRTAP19-4 | c.36C>A p.G12= | Silent (SNP) | VAF 35/49 reads (71%) | catalogued as COSV61858811; called by muse, mutect2, varscan2
- LAMA1 | c.4965A>G p.Q1655= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1196722794; called by muse, mutect2
- LPA | c.1203G>A p.S401= | Silent (SNP) | VAF 65/596 reads (11%) | catalogued as rs755484600, COSV100308288; called by muse, mutect2, varscan2
- LRP1B | c.12372T>C p.F4124= | Silent (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2, varscan2
- MSGN1 | c.552C>T p.R184= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as rs756331712, COSV55262943; called by muse, mutect2
- MUC16 | c.20436T>A p.T6812= | Silent (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- MYO1F | c.1923G>A p.T641= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs774066426; called by muse, mutect2, varscan2
- NAT16 | c.426C>T p.F142= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs746230741; called by muse, varscan2
- NLRC5 | c.121C>T p.L41= | Silent (SNP) | VAF 31/36 reads (86%) | called by muse, mutect2, varscan2
- NRXN3 | c.1629G>A p.P543= (on ENST00000557594 / NM_001272020.2; = p.P967= on NM_004796.6) | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as rs1254494576, COSV55313998, COSV55324090; called by muse, mutect2, varscan2
- OR51F2 | c.306G>A p.Q102= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.2163G>A p.K721= | Silent (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- RPAP3 | c.909A>G p.E303= | Silent (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- SBNO2 | c.3129C>T p.S1043= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1476000966, COSV62318829; called by muse, mutect2, varscan2
- SCN4A | c.4518C>T p.Y1506= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs777015227, COSV71125982; called by muse, mutect2, varscan2
- STK40 | c.735C>T p.L245= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as rs573090820; called by muse, mutect2, varscan2
- TG | c.6954C>T p.D2318= | Silent (SNP) | VAF 36/50 reads (72%) | catalogued as rs748645110, COSV55071368, COSV99061059; called by muse, mutect2, varscan2
- TRABD2A | c.1422C>T p.H474= (on ENST00000409520 / NM_001277053.2; = p.H425= on NM_001080824.3) | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1454060165; called by muse, mutect2, varscan2
- TXNRD1 | c.327A>C p.G109= (on ENST00000525566 / NM_001093771.3; = p.G11= on NM_003330.4) | Silent (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- VIP | c.96T>G p.P32= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV100923938; called by muse, mutect2, varscan2
- VWF | c.1653C>T p.N551= | Silent (SNP) | VAF 75/124 reads (60%) | catalogued as rs1381798843; called by muse, mutect2, varscan2
- WTAP | c.1002G>A p.A334= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as rs370838345; called by muse, mutect2, varscan2
- ZNF680 | c.780T>C p.H260= | Silent (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- EMC10 | c.679-234C>T | Intron (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100618495; called by muse, mutect2, varscan2
- SNORD116-24 | n.90T>C | RNA (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
